Gene-level copy-number profile of tumor specimen TCGA-GC-A3YS-01A from TCGA case TCGA-GC-A3YS, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 61.6 years (22,515 days).
Specimen TCGA-GC-A3YS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.a651a7d7-7c61-4a44-8d63-1d29746821dc.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-GC-A3YS-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4d36c096-4578-46f4-ae0d-313702693d39

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 27; copy number 1: 401; copy number 2: 7,195; copy number 3: 22,374; copy number 4: 13,220; copy number 5: 11,515; copy number 6: 2,482; copy number 7: 773; copy number 8: 155; copy number 9: 63; copy number 10: 1,267; copy number 11: 19; copy number 12: 48; copy number 14: 58; copy number 15: 97; copy number 17: 64; copy number 18: 8; copy number 19: 36; copy number 25: 3; copy number 27: 1; copy number 28: 3; copy number 30: 1; copy number 38: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-GC-A3YS-01A-11D-A23L-01): tumor purity 0.48, ploidy 3.82, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 27 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:188,974,373–189,012,746, 4 genes: COL3A1, MIR1245A, MIR1245B, MIR3606.
- chr2:194,027,919–194,664,174, 8 genes: AC068135.1, GLULP6, HNRNPA1P47, LINC01821, AC106883.1, AC073973.1, Metazoa_SRP, AC006196.1.
- chr2:201,097,744–201,357,398, 15 genes (within-gene range 0–5): Metazoa_SRP, AC007272.1, RPL17P10, CFLAR, IMPDH1P10, CFLAR-AS1, RNU7-45P, RPL38P5, AC007283.1, CASP10, MTND5P25, MTND4P23, MTND4LP13, CASP8, FLACC1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,598 genes in 31 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:159,466,321–160,372,846, 48 genes, copy number 15: LINC02819, OR10J5, AL606752.1, OR10AE1P, APCS, OR10J6P, AL445528.2, CRPP1, CRP, AL445528.1, DUSP23, FCRL6, SLAMF8, AL590560.2, SNHG28, AL590560.1, VSIG8, AL590560.3, CFAP45, MIR4259, AL590560.5, AL590560.4, TAGLN2, IGSF9, SLAMF9, LINC01133, AL513485.1, KCNJ10, AL513302.1, PIGM, AL121987.1, KCNJ9, IGSF8, ATP1A2, ATP1A4, CASQ1, AL121987.2, PEA15, DCAF8, AL139011.2, AL139011.1, RPSAP18, PEX19, COPA, SUMO1P3, Y_RNA, NCSTN, NHLH1.
- chr1:214,943,123–217,137,755, 13 genes, copy number 7 (within-gene range 5–7): AC099563.1, AC099563.2, KCNK2, VDAC1P10, AL450990.1, KCTD3, USH2A, SNORD116, AL358452.1, USH2A-AS2, USH2A-AS1, MRPS18BP1, ESRRG.
- chr1:223,992,743–248,919,946, 623 genes, copy number 7–10 (broad region; genes not listed).
- chr2:189,031,898–191,425,389, 47 genes, copy number 8: COL5A2, AC133106.1, MIR3129, KRT18P19, WDR75, KDM3AP1, AC013439.1, SLC40A1, AC012488.1, ASNSD1, ASDURF, AC012488.2, ANKAR, OSGEPL1, OSGEPL1-AS1, AC013468.1, ORMDL1, PMS1, C2orf88, TERF1P6, HNRNPCP2, RNF11P1, MSTN, HIBCH, INPP1, MFSD6, AC093388.1, NEMP2, AC108047.1, RN7SKP179, AC006460.2, NAB1, AC006460.1, AC005540.1, GLS, STAT1, RAB1AP1, AC067945.1, AC067945.2, STAT4, AC067945.3, RNU6-959P, AC079777.1, HMGB1P27, AC092614.1, MYO1B, RNU6-1045P.
- chr2:228,475,224–229,714,555, 9 genes, copy number 8 (within-gene range 3–8): LINC01807, AC012070.1, RPL7L1P10, PID1, RPL17P14, RN7SKP283, DNER, AC008273.1, RNU7-9P.
- chr2:234,438,328–234,497,081, 4 genes, copy number 7: AC097713.1, LINC01891, HSPE1P9, ARL4C.
- chr3:173,396,284–174,286,644, 4 genes, copy number 7 (within-gene range 7–28): NLGN1, AC092967.1, NLGN1-AS1, RN7SKP234.
- chr3:175,473,919–179,267,002, 48 genes, copy number 7–28: AC008180.3, RNU4-91P, AC119744.1, UBE2V1P2, RNU6-1317P, NAALADL2-AS1, AC104640.1, ACTG1P23, EI24P1, AC104640.2, AC117434.1, LINC01208, MIR7977, RNA5SP147, LINC01209, MTND5P15, TBL1XR1, TBL1XR1-AS1, Y_RNA, RNU6-681P, LINC00501, ASS1P7, AC117465.1, LINC00578, RN7SKP52, AC026355.3, AC026355.1, AC026355.2, AC026355.4, LINC02015, AC007953.1, AC007953.2, RNU6-1120P, AC110992.1, AC117453.1, KCNMB2, AC117457.1, LINC01014, RNA5SP148, PPIAP75, KCNMB2-AS1, ZMAT3, Y_RNA, AC076966.2, PIK3CA, AC076966.1, KCNMB3, LRRFIP1P1.
- chr5:58,198–55,552,554, 798 genes, copy number 8–18 (broad region; genes not listed).
- chr5:91,642,643–91,844,529, 3 genes, copy number 9: AC093298.2, PCBP2P3, AC093298.1.
- chr6:20,099,684–21,383,200, 17 genes, copy number 7 (within-gene range 5–7): MBOAT1, AL158198.1, AL158198.2, AL132775.1, AL132775.2, E2F3, RN7SL128P, E2F3-IT1, RNU6-141P, Y_RNA, CDKAL1, AL035090.1, AL513188.1, RNU6-150P, AL451080.1, AL031767.1, AL031767.2.
- chr6:65,836,930–65,838,039, 1 gene, copy number 27: ADH5P4.
- chr6:68,226,972–69,867,236, 8 genes, copy number 10–14 (within-gene range 6–14): LINC02549, AL606923.2, AL606923.1, AL391807.1, ADGRB3, LMBRD1, NPM1P37, GAPDHP42.
- chr6:155,911,195–156,505,011, 5 genes, copy number 9 (within-gene range 5–9): AL589693.1, MIR1202, AL512658.2, SNORD28B, AL512658.1.
- chr7:114,560,961–119,907,397, 73 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr7:132,648,794–141,052,409, 143 genes, copy number 7–12 (broad region; genes not listed).
- chr8:49,046,652–49,352,844, 5 genes, copy number 9–38: AC044893.2, PPDPFL, AC044893.1, RN7SKP294, RFPL4AP7.
- chr8:50,859,530–50,860,062, 1 gene, copy number 30: AC087272.1.
- chr8:124,811,042–128,187,101, 59 genes, copy number 7: AC100858.2, MIR4662B, MIR4662A, LINC00964, MRS2P1, AC100858.1, AC100858.3, ZNF572, AC009908.1, SQLE, WASHC5, WASHC5-AS1, NSMCE2, RN7SL329P, AC084083.1, TRIB1, AC091114.1, AC016074.2, AC016074.1, LINC00861, RNU6-442P, SOD1P3, AC024681.2, KNOP1P5, AC024681.1, RFPL4AP5, AC087667.1, AC084116.2, AC084116.1, RNU6-869P, AC084116.3, LRATD2, PCAT1, AC083923.1, RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208.
- chr11:55,838,752–56,394,648, 47 genes, copy number 10–19: OR5D16, OR9M1P, AC036111.2, AC036111.3, AC036111.1, TRIM51, OR5W1P, OR5W2, OR5I1, OR10AF1P, OR10AK1P, OR10AG1, OR7E5P, OR5F1, OR5F2P, OR5AS1, OR5AQ1P, OR5J1P, OR5BE1P, OR8I2, OR8I4P, OR8H2, OR5BN2P, OR8H3, OR5BN1P, OR8J3, OR8K4P, OR8K5, OR5J7P, OR5J2, OR8V1P, AC022882.1, OR8J2, OR5T2, OR5T3, OR5T1, OR8H1, OR8I1P, OR8K3, FAM8A2P, OR8K2P, OR8K1, OR8J1, RPL5P29, OR8U1, OR8L1P, OR5AL2P.
- chr11:95,821,766–95,925,315, 1 gene, copy number 8 (within-gene range 3–8): MTMR2.
- chr11:95,963,219–102,955,732, 71 genes, copy number 8–14 (broad region; genes not listed).
- chr12:52,022,832–52,406,335, 27 genes, copy number 7 (within-gene range 4–7): NR4A1, NR4A1AS, ATG101, AC025259.1, SMIM41, OR7E47P, AC078864.1, LINC00592, KRT80, LINC02874, METTL7AP1, KRT7, KRT7-AS, KRT86, KRT87P, AC021066.2, AC021066.1, AC021066.3, KRT81, AC121757.2, AC121757.1, KRT83, KRT89P, KRT85, KRT84, AC078865.1, KRT82.
- chr12:56,076,799–56,414,045, 34 genes, copy number 7: ERBB3, AC034102.2, PA2G4, AC034102.4, RPL41, ESYT1, ZC3H10, AC034102.7, AC034102.6, AC034102.5, MYL6B, MYL6, SMARCC2, AC073896.4, RNF41, NABP2, SLC39A5, ANKRD52, COQ10A, AC073896.5, CS, AC073896.1, AC073896.2, AC073896.3, CNPY2, PAN2, IL23A, STAT2, RNU7-40P, APOF, APONP, AC025574.1, AC024884.2, AC024884.1.
- chr14:27,258,717–30,737,694, 39 genes, copy number 7 (within-gene range 3–7): AL390334.1, LINC00645, MIR3171, BNIP3P1, AL139023.1, RPL26P3, LINC02300, EIF4A1P12, BTF3P2, FOXG1-AS1, AL049777.1, FOXG1, LINC01551, LINC02282, LINC02281, LINC02327, AL122126.1, LINC02326, Y_RNA, AL135878.1, RNU6-864P, AL133166.1, AL158058.1, AL158058.2, RNU11-5P, PRKD1, AL356756.1, RNU6-1234P, AL355053.1, AL133372.3, AL133372.2, AL133372.1, AL079305.1, G2E3-AS1, AL117355.1, SYF2P1, G2E3, SCFD1, UBE2CP1.
- chr16:52,078,622–52,099,120, 4 genes, copy number 7: AC009039.1, AC009039.2, LINC00919, LINC02180.
- chr18:29,629,842–29,650,440, 1 gene, copy number 10: AC117569.2.
- chr18:48,539,031–48,863,217, 1 gene, copy number 7 (within-gene range 2–7): CTIF.
- chr18:48,661,840–48,963,941, 7 genes, copy number 7: AC048380.3, MIR4743, AC048380.1, AC022919.1, AC093567.1, SMAD7, AC114684.1.
- chr19:28,790,812–30,228,715, 37 genes, copy number 10: MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1.
- chr19:30,850,975–40,465,764, 420 genes, copy number 7–25 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 401. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
